Gene-level copy-number profile of tumor specimen TCGA-DD-A4NO-01A from TCGA case TCGA-DD-A4NO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 66.0 years (24,090 days).
Specimen TCGA-DD-A4NO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.d471d7de-2e99-44e2-aa59-c571ff23ff9a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A4NO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ddde00c7-7260-4341-87b5-b92080054c66

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 306; copy number 2: 22,323; copy number 3: 3,721; copy number 4: 25,080; copy number 5: 3,180; copy number 6: 1,186; copy number 7: 4,020; copy number 11: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A4NO-01A-11D-A28W-01): tumor purity 0.61, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:3,249,305–3,407,625, 3 genes, copy number 11 (within-gene range 1–11): C20orf194, RNU6-1019P, UBE2V1P1.

Autosomal genes at a single copy (total copy number 1): 306. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
